HCMI case HCM-CSHL-0654-C26 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c5d2e21e-6987-4085-8c67-9d41630957b5

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1948.

Diagnoses (2)
1. Carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8010/3; ICD-10 code: C26.9; Tissue or organ of origin: Unknown primary site; Classification of tumor: primary; Age at diagnosis: 70.6 years (25,800 days); Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Sites of involvement: Lymph node, NOS.
   Recorded as not given: Surgery, NOS, for initial diagnosis.
2. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8010/6; ICD-10 code: C79.9; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 70.6 years (25,800 days).

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Follow-up contact recording only the day: day 148.

Molecular and laboratory tests
- CD274 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 84 kg; Height: 170.2 cm; BMI: 29.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0654-C26-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0654-C26-06A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
  Slide HCM-CSHL-0654-C26-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 9; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample HCM-CSHL-0654-C26-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0654-C26-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
